Somatic mutation profile of tumor specimen TARGET-10-PARGJY-09A (aliquot TARGET-10-PARGJY-09A-01D) from TARGET case TARGET-10-PARGJY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.8 years (6,501 days).
Specimen TARGET-10-PARGJY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94829da3-58e1-46ee-88a7-501930939d90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGJY-10A (Blood Derived Normal), aliquot TARGET-10-PARGJY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a0d0713-11ae-40d3-9018-ead9b15a2be1

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 2, 5'UTR 1, RNA 1, Frame Shift Ins 1, Splice Site 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 16/85 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- C2orf16 | c.4654G>A p.G1552S | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs372841332; called by muse, mutect2, varscan2
- HPX | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs142045379, COSV56421064; called by muse, mutect2, varscan2
- MECOM | c.1290G>A p.M430I (on ENST00000468789 / NM_001105078.4; = p.M618I on NM_004991.4) | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV52964690; called by muse, mutect2, varscan2
- NRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV65731978; called by muse, mutect2
- PROM1 | c.2122G>C p.G708R | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.716); catalogued as COSV71699437, COSV71699678; called by muse, mutect2, varscan2
- ZEB2 | c.3113A>G p.H1038R | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57953045; called by muse, mutect2, varscan2
- ABCA3 | c.2769G>A p.W923* | Nonsense Mutation (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- ACVR2B | c.397_398insTTTT p.P133Lfs*43 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- FHDC1 | c.663+1G>A p.X221_splice | Splice Site (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- KMT2D | c.4425_4426del p.S1476Lfs*14 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | called by pindel, varscan2*
- SUV39H1 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TTN | c.41257G>T p.V13753L (on ENST00000591111; = p.V6329L on NM_003319.4) | Missense Mutation (SNP) | VAF 49/102 reads (48%) | PolyPhen benign (0.011); called by muse, mutect2, varscan2
- VN1R5 | c.644C>A p.T215N | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- VPS13C | c.4562A>G p.K1521R (on ENST00000644861 / NM_020821.3; = p.K1478R on NM_017684.5) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFP28 | c.2594_2597del p.L865Hfs*91 | Frame Shift Del (DEL) | VAF 30/80 reads (38%) | called by pindel, varscan2
- CLDN10 | c.189G>A p.P63= | Silent (SNP) | VAF 46/81 reads (57%) | catalogued as COSV65300122; called by muse, mutect2, varscan2
- FLT4 | c.2553C>T p.L851= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs756742987; called by muse, mutect2, varscan2
- GRIK5 | c.1962G>A p.S654= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs782033578, COSV53477923; called by muse, mutect2, varscan2
- CCDC140 | n.517C>A | RNA (SNP) | VAF 46/106 reads (43%) | called by muse, mutect2, varscan2
- RAD21 | chr8:116874912 A>C | 5'Flank (SNP) | VAF 82/135 reads (61%) | called by muse, mutect2, varscan2
- SP3 | c.-84G>A | 5'UTR (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
